CCDI case PBCMID — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/b3fd8486-4c98-433d-86e7-d764075c42dd

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 16.7 years (6,113 days).

Biospecimens (2 samples)
- Sample 0DV4IV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4J7: Tissue type: Tumor; Specimen type: Solid Tissue.
